Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5521, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5521-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 7.3 which increased from 6.31. The patient also has a history of [REDACTED] which reveals a Gleason Grade of 3+3=6 on the right lobe. Patient has a past medical history of dental [REDACTED].

PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, EXCISION –
ONE BENIGN LYMPH NODE.

TCGA – EJ – 5521

PART 2: LYMPH NODE, LEFT PELVIS, EXCISION –
ONE BENIGN LYMPH NODE.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 WITH A DISTINCT FOAMY MORPHOLOGY.
- B. THE CARCINOMA INVOLVES PREDOMINANTLY THE RIGHT LOBE AND HAS A GREATEST NODULAR DIAMETER OF 1.8 CM.
- C. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- D. EXTRACAPSULAR PROSTATIC EXTENSION IS PRESENT IN THE REGIONS OF ANTERIOR RIGHT BASE (SLIDE 3Q) AND POSTERIOR RIGHT BASE (SLIDE 3Z).
- E. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- F. EXTENSIVE PERINEURAL INVASION IS SEEN.
- G. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS IDENTIFIED.
- H. BILATERAL SEMINAL VESICLES ARE NOT INVOLVED BY TUMOR.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- K. TNM HISTOLOGIC GRADE = G3.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 7.3
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS ✓
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	53.47gm
TUMOR SIZE:	Maximum dimension: 1.8 cm
LOBE LATERALITY:	Right Lobe
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	2
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file d9e917a0-efc5-42f2-b176-626aec2efcf8 (TCGA-EJ-5521.0C816088-3FE4-4646-ABAA-94095EFD0B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).